Gene-level copy-number profile of tumor specimen TCGA-K4-A54R-01A from TCGA case TCGA-K4-A54R, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Dome of bladder; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 59.1 years (21,601 days).
Specimen TCGA-K4-A54R-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.8a61778b-676f-4115-9341-16c31e7e97b8.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-K4-A54R-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 372 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3558ae07-43cb-42af-be81-d5be4572300d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2,002; copy number 1: 9,865; copy number 2: 45,153; copy number 3: 2,942; copy number 4: 113; copy number 5: 100; copy number 6: 42; copy number 7: 7; copy number 8: 7; copy number 9: 1; copy number 10: 19.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-K4-A54R-01A-11D-A26L-01): tumor purity 0.46, ploidy 3.62, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 434 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:168,092,537–189,709,714, 292 genes (broad region; genes not listed).
- chr5:178,825,382–178,842,235, 3 genes: AC126915.2, AC126915.1, AC126915.3.
- chr6:165,327,287–170,738,536, 129 genes (within-gene range 0–1) (broad region; genes not listed).
- chr9:3,364,329–3,364,792, 1 gene: AL354941.1.
- chr9:91,206,175–91,210,299, 1 gene: AL158071.4.
- chr10:75,642,476–75,643,106, 1 gene: AL589863.1.
- chr11:48,579,436–48,580,336, 1 gene: OR4A45P.
- chr11:63,163,776–63,229,652, 1 gene (within-gene range 0–2): SLC22A25.
- chr12:65,050,626–65,121,305, 2 genes (within-gene range 0–2): WIF1, RNU6-166P.
- chr16:28,179,098–28,183,430, 2 genes: AC136611.1, RNY1P10.
- chr17:41,271,311–41,271,835, 1 gene: KRTAP9-11P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 176 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:109,249,539–110,674,940, 61 genes, copy number 6–10 (broad region; genes not listed).
- chr2:97,113,153–97,264,521, 1 gene, copy number 7: ANKRD36.
- chr3:130,081,831–130,201,336, 6 genes, copy number 7 (within-gene range 2–7): ALG1L2, LINC02014, FAM86HP, LINC02021, ENPP7P3, AC130888.1.
- chr4:49,203,171–49,246,915, 7 genes, copy number 8: AC118282.3, AC118282.2, AC118282.4, SNX18P23, AC118282.1, MTCO3P39, MTND3P22.
- chr8:37,326,575–39,838,289, 72 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).
- chr8:46,028,804–46,028,892, 1 gene, copy number 5: AC118650.1.
- chr10:95,109,136–95,111,642, 1 gene, copy number 9: AL157834.1.
- chr15:25,135,642–25,213,729, 27 genes, copy number 5: PWAR1, SNORD115, DMAC1P1, SNORD115-1, SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24.

Autosomal genes at a single copy (total copy number 1): 9,865. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
